Somatic mutation profile of tumor specimen TCGA-V4-A9E7-01A (aliquot TCGA-V4-A9E7-01A-11D-A39W-08) from TCGA case TCGA-V4-A9E7, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 76.7 years (28,025 days).
Specimen TCGA-V4-A9E7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 959eede6-60fb-4181-93ad-74d561af37c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9E7-10A (Blood Derived Normal), aliquot TCGA-V4-A9E7-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7cf3c6b-6e23-49c6-9a04-40995c07435e

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 13, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 41/77 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP13A5 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 48/55 reads (87%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as rs747489400, COSV100665007; called by muse, mutect2, varscan2
- COL12A1 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT tolerated (0.41); PolyPhen benign (0.166); catalogued as rs201657576, COSV59403671; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT3 | c.12992G>T p.G4331V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs1218254092; called by muse, mutect2, varscan2
- IL1R1 | c.1545G>C p.W515C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753616565; called by muse, mutect2, varscan2
- MUC16 | c.2414G>A p.S805N | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.266); catalogued as rs773114784, COSV101200642; called by muse, mutect2, varscan2
- PCDHB4 | c.1528G>A p.G510S | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782629770; called by muse, mutect2, varscan2
- PRDM9 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as COSV57002975; called by muse, varscan2
- RAB2B | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.664); catalogued as rs780512676; called by muse, mutect2, varscan2
- ALKBH7 | c.473del p.L158Cfs*43 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | called by mutect2, pindel, varscan2
- CD109 | c.1631G>T p.S544I | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- FBXO10 | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2
- INPP5A | c.1235A>T p.Q412L | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- OR6C65 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- FCSK | c.336C>T p.P112= | Silent (SNP) | VAF 30/38 reads (79%) | catalogued as rs770830036; called by muse, mutect2, varscan2
- TNPO1 | c.1416C>T p.R472= | Silent (SNP) | VAF 36/96 reads (38%) | called by muse, mutect2, varscan2
